Somatic mutation profile of tumor specimen TARGET-30-PATUEH-01A (aliquot TARGET-30-PATUEH-01A-01D) from TARGET case TARGET-30-PATUEH, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 2.5 years (908 days).
Specimen TARGET-30-PATUEH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f35af64-cf81-4ff8-a5bd-b98220df122d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATUEH-10A (Blood Derived Normal), aliquot TARGET-30-PATUEH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87d0233d-be46-48ca-af05-63dde0c79048

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.1928G>T p.G643V | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV59267789; called by muse, mutect2, varscan2
- RYR1 | c.1794C>T p.V598= | Splice Region (SNP) | VAF 68/150 reads (45%) | catalogued as COSV62099816; called by muse, mutect2, varscan2
